Somatic mutation profile of tumor specimen TCGA-50-5933-01A (aliquot TCGA-50-5933-01A-11D-1753-08) from TCGA case TCGA-50-5933, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.2 years (26,377 days).
Specimen TCGA-50-5933-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fee4c11a-1bad-4007-82c2-f707ac2c7f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5933-11A (Solid Tissue Normal), aliquot TCGA-50-5933-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c4b4e72-abfc-4f2c-b2d8-cfa019c0f548

The open-access MAF lists 532 somatic variants for this specimen: 402 protein-altering or splice-affecting, 118 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 350, Silent 118, Nonsense Mutation 24, Frame Shift Del 11, Frame Shift Ins 6, Splice Site 6, Intron 6, Splice Region 3, RNA 3, 3'UTR 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPYD | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 6/67 reads (9%) | catalogued as rs1057516968, CM161357, COSV64613429; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- THSD7B | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55688858; called by muse, mutect2, varscan2
- TP53 | c.560-1G>T p.X187_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | hotspot (GDC flag); catalogued as CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; called by muse, mutect2, varscan2
- ABCA7 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV54036755; called by muse, mutect2, varscan2
- ABCB11 | c.3950G>C p.G1317A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV55600282; called by muse, mutect2
- ABCB4 | c.1057T>A p.C353S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV55941252; called by muse, mutect2, varscan2
- ABCG2 | c.1594A>T p.S532C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs777763707, COSV52949222; called by muse, mutect2, varscan2
- ABRA | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1342016080; called by muse, mutect2
- ACP3 | c.649-1G>C p.X217_splice | Splice Site (SNP) | VAF 6/94 reads (6%) | catalogued as COSV60488468; called by muse, mutect2
- ACSM2B | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373308064, COSV100313364; called by muse, mutect2, varscan2
- ACSM2B | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV61659836; called by muse, mutect2
- ACTN2 | c.129C>A p.T43= | Splice Region (SNP) | VAF 7/23 reads (30%) | catalogued as COSV63977991; called by muse, mutect2, varscan2
- ACTRT1 | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.322); catalogued as COSV64419987; called by muse, mutect2, varscan2
- ADAM28 | c.375G>C p.R125S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.192); catalogued as COSV56105087, COSV99737699; called by muse, mutect2, varscan2
- ADGRG6 | c.2594C>G p.T865S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51600522; called by muse, mutect2, varscan2
- ADH6 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.904); catalogued as COSV52957747; called by muse, mutect2, varscan2
- AHNAK2 | c.10529C>A p.S3510Y | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV60929318; called by muse, mutect2
- ALDH1L2 | c.2195G>C p.G732A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51559597; called by muse, mutect2, varscan2
- ANK2 | c.5900G>C p.G1967A | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV52186707; called by muse, mutect2, varscan2
- ANKMY2 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61012666; called by muse, mutect2
- ANKRD17 | c.4045C>T p.R1349C | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442131714, COSV58227285; called by muse, mutect2, varscan2
- ARFGEF2 | c.2311G>T p.V771F | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1367236691, COSV64214918; called by muse, mutect2, varscan2
- ARFGEF3 | c.4090G>T p.G1364* | Nonsense Mutation (SNP) | VAF 15/190 reads (8%) | catalogued as COSV52458685; called by muse, mutect2
- ARMC4 | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762051082, COSV59473037; called by muse, mutect2, varscan2
- ASZ1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534630019, COSV52916211; called by muse, mutect2, varscan2
- ATF7IP | c.1007A>T p.D336V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as COSV53776966; called by muse, mutect2, varscan2
- ATPSCKMT | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559270054, COSV54726807, COSV99725982; called by muse, mutect2, varscan2
- BAMBI | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs749500911, COSV65003106; called by muse, mutect2, varscan2
- BMS1 | c.3149C>T p.A1050V | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.596); catalogued as COSV65735389; called by muse, mutect2, varscan2
- BNC2 | c.539A>T p.Q180L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV66156527; called by muse, mutect2, varscan2
- BRWD3 | c.478C>A p.H160N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV64753248; called by muse, mutect2, varscan2
- C7orf26 | c.343G>T p.G115* | Nonsense Mutation (SNP) | VAF 31/194 reads (16%) | catalogued as COSV60107036; called by muse, mutect2, varscan2
- CAMK1D | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs148446769; called by mutect2, varscan2
- CAPN6 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.048); catalogued as COSV60697082; called by muse, mutect2, varscan2
- CASR | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.054); catalogued as CM149034, COSV56141158; called by muse, mutect2, varscan2
- CBFA2T2 | c.50G>T p.R17M | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV60075753; called by muse, mutect2, varscan2
- CBLN3 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs1020860730, COSV52160465; called by muse, mutect2, varscan2
- CCDC186 | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.238); catalogued as COSV65159501, COSV65159593; called by muse, mutect2, varscan2
- CD1E | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as rs1412585250, COSV63771029, COSV63772756; called by muse, mutect2, varscan2
- CD48 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs372863860, COSV63567587; called by muse, mutect2, varscan2
- CD5L | c.919C>A p.R307S | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV63823026; called by muse, mutect2, varscan2
- CDH11 | c.1173A>T p.E391D | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs750088925, COSV51769106, COSV51776335; called by muse, mutect2, varscan2
- CDH13 | c.1369G>T p.G457C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51788416, COSV51865214; called by muse, mutect2
- CDH23 | c.4250G>A p.R1417Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369353175; called by muse, mutect2, varscan2
- CHD6 | c.6234G>C p.Q2078H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV64694166; called by muse, mutect2
- CHIT1 | c.1262A>T p.Q421L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.258); catalogued as COSV55149786; called by muse, mutect2, varscan2
- CHRM2 | c.1261G>T p.V421L | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV57783823; called by muse, mutect2, varscan2
- CHRM3 | c.1714C>A p.Q572K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV55102864; called by muse, mutect2, varscan2
- CLIP2 | c.2857C>A p.L953M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV56285688; called by muse, mutect2, varscan2
- CNOT9 | c.748A>T p.R250* | Nonsense Mutation (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99813839; called by muse, mutect2
- CNTNAP1 | c.100T>C p.Y34H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.859); catalogued as COSV52854193; called by muse, mutect2, varscan2
- CNTNAP5 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV70510357; called by muse, mutect2, varscan2
- COASY | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99888791; called by muse, mutect2, varscan2
- COL12A1 | c.6079G>T p.G2027* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV59407144; called by muse, mutect2, varscan2
- COL5A1 | c.1466C>A p.T489N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV65674258; called by muse, mutect2, varscan2
- COL6A3 | c.2728A>G p.T910A | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.334); catalogued as rs1198902358, COSV55107873; called by muse, mutect2, varscan2
- COPB2 | c.409G>C p.V137L | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV60813813; called by muse, mutect2, varscan2
- CPED1 | c.2600A>G p.N867S | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV60012396; called by muse, mutect2, varscan2
- CPNE2 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV51964859, COSV99321207; called by muse, mutect2
- CPVL | c.814C>A p.H272N | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55308107; called by muse, mutect2, varscan2
- CRYGA | c.349C>G p.R117G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV58018980; called by mutect2, varscan2
- CSMD2 | c.3423G>T p.R1141S | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV53958400; called by muse, mutect2, varscan2
- CSMD3 | c.10927A>C p.I3643L (on ENST00000297405 / NM_001363185.1; = p.I3474L on NM_052900.3) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52307638; called by muse, mutect2, varscan2
- CSRNP3 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV58785193; called by muse, mutect2, varscan2
- CTDP1 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50008807; called by muse, mutect2
- CTNND2 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.824); catalogued as COSV58924824; called by muse, mutect2, varscan2
- CUL1 | c.1382T>G p.V461G | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57392256; called by muse, mutect2, varscan2
- CUZD1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs143659470; called by muse, mutect2, varscan2
- CYLC1 | c.1494C>A p.H498Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100255436; called by muse, mutect2, varscan2
- CYLC1 | c.1495T>C p.S499P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100255445; called by muse, mutect2, varscan2
- DCSTAMP | c.509C>A p.T170N | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as rs1323382081, COSV52580015; called by muse, mutect2, varscan2
- DDR2 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV63374153; called by muse, mutect2, varscan2
- DDR2 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV63374160; called by muse, mutect2
- DDX3X | c.821C>T p.T274M (on ENST00000399959; = p.T275M on NM_001356.5) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863061; called by muse, mutect2, varscan2
- DHX8 | c.126G>T p.L42F | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV52255375; called by muse, mutect2, varscan2
- DIAPH3 | c.3055del p.R1019Efs*12 (on ENST00000400324 / NM_001042517.2; = p.R756Efs*12 on NM_030932.3) | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs753024929; called by mutect2, pindel, varscan2
- DIP2C | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55177780; called by muse, varscan2
- DISP3 | c.2843G>A p.R948H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs12096312, COSV53833631; called by muse, mutect2, varscan2
- DMD | c.4838G>C p.W1613S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM132410, COSV63789091; called by muse, mutect2, varscan2
- DMXL1 | c.4703G>T p.G1568V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60720275; called by muse, mutect2
- DNAH2 | c.4073C>T p.A1358V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66726621; called by muse, mutect2, varscan2
- DNAJC5G | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56081167; called by muse, mutect2, varscan2
- DOCK2 | c.1262A>T p.D421V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV56985784; called by muse, mutect2
- DST | c.18220G>T p.D6074Y (on ENST00000361203 / NM_001374722.1; = p.D3771Y on NM_015548.5) | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55038334; called by muse, mutect2, varscan2
- EBI3 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55691243; called by mutect2, varscan2
- EIF4A2 | c.849G>T p.R283S | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV56218580; called by muse, mutect2, varscan2
- ELAPOR1 | c.2825C>T p.S942F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64040362, COSV64041221; called by muse, mutect2, varscan2
- ELOA2 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV55308048; called by muse, mutect2
- EMILIN2 | c.2854T>A p.Y952N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54427235; called by muse, mutect2
- EPB41L2 | c.1267G>T p.V423L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61358804, COSV61359482; called by muse, mutect2, varscan2
- EPHA3 | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV60725866; called by muse, mutect2, varscan2
- EPHB6 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs763847812, COSV100844263, COSV63893534; called by mutect2, varscan2
- ERICH3 | c.3787G>A p.G1263R | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs754885612, COSV58617355; called by muse, mutect2, varscan2
- ERICH3 | c.3138G>C p.R1046S | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV58602820, COSV58617367; called by muse, mutect2, varscan2
- ERICH3 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV58617379; called by muse, mutect2, varscan2
- ERRFI1 | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV101088282; called by muse, mutect2, varscan2
- EVI2B | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1224374558, COSV100445655; called by muse, mutect2
- EXOC8 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs748623243, COSV50479664; called by mutect2, varscan2
- EXOSC4 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as rs1554763312, COSV60156496; called by muse, mutect2, varscan2
- EYA4 | c.1875G>T p.W625C (on ENST00000531901 / NM_001301013.1; = p.W619C on NM_004100.5) | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62060160; called by muse, mutect2, varscan2
- F2 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV61317608; called by muse, mutect2, varscan2
- FAM135B | c.3050C>A p.A1017E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV52751618; called by muse, mutect2, varscan2
- FAT1 | c.3706C>T p.L1236F | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71675861; called by muse, mutect2, varscan2
- FAT2 | c.3035C>A p.T1012N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV55828769; called by muse, mutect2, varscan2
- FAT3 | c.6116G>A p.G2039E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53169834; called by muse, mutect2, varscan2
- FBN3 | c.5769T>A p.D1923E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV54472048; called by muse, mutect2
- FCRLA | c.697T>A p.Y233N (on ENST00000367959; = p.Y210N on NM_032738.4) | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52688258; called by muse, mutect2, varscan2
- FER | c.2102G>A p.S701N | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55294345; called by muse, mutect2, varscan2
- FER1L6 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV67552647; called by muse, mutect2, varscan2
- FLG | c.1742C>A p.T581N | Missense Mutation (SNP) | VAF 91/441 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV64248374; called by muse, mutect2, varscan2
- FLG | c.1594C>A p.H532N | Missense Mutation (SNP) | VAF 63/647 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs758635510, COSV64236350; called by muse, mutect2
- FLG2 | c.956C>A p.S319* | Nonsense Mutation (SNP) | VAF 33/292 reads (11%) | catalogued as COSV66172880; called by muse, mutect2, varscan2
- FLT3 | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV54052050, COSV54069185; called by muse, mutect2, varscan2
- FLT4 | c.2675C>T p.A892V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56121298, COSV99987729; called by muse, mutect2, varscan2
- FNDC3A | c.2450A>T p.K817I (on ENST00000492622 / NM_001079673.2; = p.K761I on NM_014923.5) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV68134948; called by muse, mutect2, varscan2
- FOXG1 | c.842G>C p.R281P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57399395; called by muse, varscan2
- FPGT-TNNI3K | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV58556971; called by muse, mutect2, varscan2
- FRYL | c.8359G>A p.D2787N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51938900; called by muse, mutect2, varscan2
- FYB1 | c.1640A>T p.E547V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60955857; called by muse, mutect2, varscan2
- GADL1 | c.789G>T p.G263= | Splice Region (SNP) | VAF 13/75 reads (17%) | catalogued as rs750146052, COSV56985272; called by muse, mutect2, varscan2
- GALNT13 | c.1155A>C p.P385= | Splice Region (SNP) | VAF 10/129 reads (8%) | catalogued as COSV67220789, COSV67237628; called by muse, mutect2
- GATA4 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM110562, COSV58735625; called by muse, mutect2, varscan2
- GNG12 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100921423; called by muse, mutect2, varscan2
- GOLGB1 | c.6876G>T p.Q2292H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61464961, COSV61470609; called by muse, mutect2, varscan2
- GRHL1 | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV61408058; called by muse, mutect2, varscan2
- GRIA2 | c.46T>A p.W16R | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV52404804; called by muse, mutect2, varscan2
- GRM8 | c.658A>T p.T220S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV58864804; called by muse, mutect2
- HCN4 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56087068, COSV56087290; called by muse, mutect2, varscan2
- HDAC4 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV61875503; called by muse, mutect2, varscan2
- HELQ | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55024987; called by muse, mutect2, varscan2
- HID1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59352295; called by muse, mutect2
- HIF1A | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 19/173 reads (11%) | catalogued as COSV60188485; called by muse, mutect2, varscan2
- HMCN1 | c.10895C>T p.T3632I | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54938495; called by muse, mutect2, varscan2
- HOXB3 | c.767C>A p.S256* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | catalogued as COSV57488184; called by muse, mutect2, varscan2
- HPSE2 | c.136C>G p.P46A | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV65200814; called by muse, mutect2, varscan2
- HSD3B2 | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs747237944, COSV65593981; called by muse, mutect2, varscan2
- HTR1A | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.602); catalogued as COSV60502834, COSV60503700; called by muse, mutect2, varscan2
- HTR1A | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs555710952; called by muse, mutect2, varscan2
- HYAL4 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.745); catalogued as COSV99772452; called by muse, mutect2, varscan2
- IGF2BP3 | c.956C>A p.T319K | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV51692789; called by muse, mutect2, varscan2
- IGSF22 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV60030815; called by muse, mutect2
- IL17RE | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV55968300, COSV99925263; called by muse, mutect2, varscan2
- IL1RL2 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV51818653; called by muse, mutect2, varscan2
- IL33 | c.440T>A p.V147D | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101197919; called by muse, mutect2, varscan2
- IPMK | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV64243517; called by muse, mutect2, varscan2
- ITGA2 | c.3086G>T p.G1029V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV56866048; called by muse, mutect2, varscan2
- ITIH6 | c.2762C>A p.S921Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV54494228; called by muse, mutect2, varscan2
- ITPRID1 | c.2261C>A p.A754E | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV60082137; called by muse, mutect2
- KALRN | c.1652G>A p.W551* | Nonsense Mutation (SNP) | VAF 48/208 reads (23%) | catalogued as COSV53779257; called by muse, mutect2, varscan2
- KATNA1 | c.4A>G p.S2G | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as rs1326322121, COSV59503922; called by muse, mutect2, varscan2
- KCNA2 | c.1335G>C p.K445N | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as COSV60371425; called by muse, mutect2, varscan2
- KCNA2 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60369330, COSV60370715; called by muse, mutect2, varscan2
- KCNJ3 | c.491T>A p.F164Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54544007; called by muse, varscan2
- KCNS2 | c.101C>A p.T34K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV54637580, COSV54641009; called by muse, mutect2, varscan2
- KIAA0319 | c.2254T>A p.Y752N | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65501834; called by muse, mutect2
- KIRREL1 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63291050; called by muse, mutect2
- KLHL1 | c.1579A>T p.N527Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64782960; called by muse, mutect2, varscan2
- KPRP | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV100908655, COSV64222934; called by muse, mutect2, varscan2
- KRT38 | c.1212C>A p.Y404* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV55847546; called by muse, mutect2, varscan2
- KRT6A | c.1166A>G p.Q389R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV58107708; called by muse, mutect2, varscan2
- KRT73 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV99988849; called by muse, mutect2
- KRT82 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 18/261 reads (7%) | catalogued as COSV57787160; called by muse, mutect2
- KRTAP4-3 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1316501671, COSV101194175; called by muse, varscan2
- KRTAP4-4 | c.410A>C p.Q137P | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV66811536; called by muse, mutect2, varscan2
- LARP4 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53326987; called by muse, mutect2, varscan2
- LEPR | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60763837; called by muse, mutect2, varscan2
- LMX1A | c.580C>A p.R194S | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54227573; called by muse, mutect2
- LPA | c.3656A>T p.N1219I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60311189; called by muse, mutect2
- LRP1B | c.12256T>C p.Y4086H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV67271082; called by muse, mutect2, varscan2
- LRRN4CL | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs1214851276; called by muse, mutect2
- LUM | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as COSV57128146, COSV57129467; called by muse, mutect2, varscan2
- MAD2L1BP | c.304_306del p.S102del | In Frame Del (DEL) | VAF 11/96 reads (11%) | catalogued as rs1436883374; called by mutect2, pindel, varscan2
- MAGEA11 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV60758580; called by muse, mutect2, varscan2
- MAGEA12 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.976); catalogued as COSV63295423; called by muse, mutect2, varscan2
- MDH1B | c.887G>T p.R296I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV65588567, COSV65591648; called by muse, mutect2, varscan2
- MDN1 | c.15859G>A p.E5287K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV101021805; called by muse, mutect2, varscan2
- MEGF10 | c.1731G>A p.W577* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV57256010; called by muse, mutect2, varscan2
- MET | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59268502; called by muse, mutect2, varscan2
- MLH1 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs587778913, COSV51624094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMS22L | c.1748A>T p.Q583L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV51526281; called by muse, mutect2, varscan2
- MMUT | c.1621G>T p.A541S | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); catalogued as COSV51282426; called by muse, mutect2, varscan2
- MPHOSPH10 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV54907109; called by muse, mutect2, varscan2
- MST1R | c.3427G>A p.V1143M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV56573594; called by muse, mutect2, varscan2
- MUC17 | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1562804217, COSV60302385; called by muse, mutect2, varscan2
- MUC17 | c.9985A>T p.S3329C | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60302395; called by muse, mutect2, varscan2
- MYH8 | c.3577G>T p.A1193S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV67971854; called by muse, mutect2, varscan2
- MYO7B | c.1803G>T p.K601N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV101268376; called by muse, mutect2, varscan2
- NARF | c.521-1G>T p.X174_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV59113566; called by muse, mutect2, varscan2
- NCKAP5 | c.3226C>A p.L1076M | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV58473143; called by muse, mutect2
- NEO1 | c.2239G>T p.V747L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56066870, COSV56077782; called by muse, mutect2, varscan2
- NFIC | c.656G>C p.S219T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as COSV59413951, COSV59416338; called by muse, mutect2, varscan2
- NHLRC3 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61489512; called by muse, mutect2, varscan2
- NID2 | c.2039C>G p.T680R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53502434; called by muse, mutect2, varscan2
- NLRP13 | c.965G>C p.R322P | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV61623915; called by muse, mutect2, varscan2
- NPSR1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62207240; called by muse, mutect2, varscan2
- NPY5R | c.487G>T p.V163F | Missense Mutation (SNP) | VAF 86/327 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV58453836; called by muse, mutect2, varscan2
- NRAP | c.3236C>A p.S1079Y (on ENST00000359988 / NM_001322945.2; = p.S1044Y on NM_006175.4) | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.63); catalogued as COSV63493687; called by muse, mutect2
- NT5C1A | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV52493216, COSV52496278; called by muse, mutect2, varscan2
- NUP214 | c.6059G>T p.S2020I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63907330, COSV63912955; called by muse, mutect2, varscan2
- OGDHL | c.2737A>G p.I913V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV65104510; called by muse, mutect2, varscan2
- OPRPN | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV68193586; called by muse, mutect2, varscan2
- OR10G8 | c.73del p.L25Sfs*22 | Frame Shift Del (DEL) | VAF 43/181 reads (24%) | catalogued as rs1383077583; called by mutect2, pindel, varscan2
- OR10V1 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV55701047; called by muse, mutect2, varscan2
- OR14K1 | c.310_311insA p.L104Hfs*16 | Frame Shift Ins (INS) | VAF 10/79 reads (13%) | catalogued as COSV99315455; called by mutect2, pindel, varscan2
- OR1S2 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56920662; called by muse, mutect2, varscan2
- OR2A5 | c.895G>C p.G299R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV68738720, COSV68739112; called by muse, mutect2
- OR2B3 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101013785; called by muse, mutect2, varscan2
- OR2J2 | c.657T>G p.Y219* | Nonsense Mutation (SNP) | VAF 18/132 reads (14%) | catalogued as COSV65848358; called by muse, mutect2, varscan2
- OR2L2 | c.566C>A p.T189K | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.102); catalogued as COSV63560394; called by muse, mutect2, varscan2
- OR4K17 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as rs868786130, COSV59649048; called by muse, mutect2, varscan2
- OR4N5 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100374074, COSV61321295; called by muse, mutect2, varscan2
- OR51A7 | c.928T>A p.C310S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.01); catalogued as COSV63788925; called by mutect2, varscan2
- OR5D13 | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV62335220; called by muse, mutect2, varscan2
- OR5I1 | c.751A>T p.T251S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV100041684; called by muse, mutect2
- OR5J2 | c.629C>G p.T210S | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as COSV56620683, COSV56623040; called by muse, mutect2, varscan2
- OR5T1 | c.282G>T p.L94F | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1431988258, COSV100479219; called by muse, mutect2, varscan2
- OR5T1 | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as COSV100479220; called by muse, mutect2, varscan2
- OR6N1 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58647755, COSV58650332; called by muse, mutect2, varscan2
- OR8H3 | c.236C>G p.T79R | Missense Mutation (SNP) | VAF 49/493 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57911468; called by muse, mutect2, varscan2
- ORC5 | c.1305G>T p.L435F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99033841; called by muse, mutect2, varscan2
- OVCH1 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58967878; called by muse, mutect2
- P2RY10 | c.841C>G p.R281G | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as COSV50680374, COSV99409376; called by muse, mutect2, varscan2
- P2RY10 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs377090188, COSV99409380; called by muse, mutect2, varscan2
- PAK5 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV62037205; called by muse, mutect2, varscan2
- PAPPA2 | c.3042T>G p.D1014E | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV62810656; called by muse, mutect2, varscan2
- PARP2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.725); catalogued as COSV99163049; called by muse, mutect2, varscan2
- PBLD | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53267214; called by muse, mutect2, varscan2
- PCDH11X | c.2610G>T p.K870N | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs754244107, COSV53501376; called by muse, mutect2, varscan2
- PCDH11X | c.2815T>C p.Y939H | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53501417; called by muse, mutect2, varscan2
- PCDH15 | c.4630A>T p.T1544S | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.12); catalogued as COSV64694118, COSV64733797; called by muse, mutect2, varscan2
- PCDH15 | c.3964G>A p.D1322N | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as rs1411262816, CD1413509, COSV57387920; called by muse, mutect2, varscan2
- PCDH18 | c.2048T>A p.V683E | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV61271875; called by muse, mutect2, varscan2
- PCDHA1 | c.1160G>T p.C387F | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65376796; called by muse, mutect2, varscan2
- PCDHA11 | c.1925C>G p.P642R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV56542740; called by muse, mutect2, varscan2
- PCDHA4 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs782686583, COSV63545719; called by muse, mutect2, varscan2
- PCDHB5 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV50668995; called by muse, mutect2, varscan2
- PCDHB5 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs931024122, COSV50669041; called by muse, mutect2, varscan2
- PCLO | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV61645667, COSV61668604; called by muse, mutect2, varscan2
- PDE4D | c.1885C>T p.Q629* (on ENST00000340635 / NM_001104631.2; = p.Q493* on NM_006203.4) | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as COSV57720514; called by muse, mutect2, varscan2
- PDILT | c.1006G>T p.V336F | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56700910, COSV56705057; called by muse, mutect2, varscan2
- PIK3C3 | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV56284174; called by muse, varscan2
- PKHD1 | c.2854G>T p.G952* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as CM054810, COSV61893578, COSV61898105; called by muse, mutect2
- PLCB4 | c.3496G>C p.E1166Q (on ENST00000278655 / NM_182797.3; = p.R1178P on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.301); catalogued as COSV53816676, COSV53820270; called by muse, mutect2, varscan2
- PLCE1 | c.1986C>A p.F662L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.968); catalogued as COSV53370566; called by muse, mutect2, varscan2
- PLEKHS1 | c.607G>A p.V203M (on ENST00000369310 / NM_182601.1; = p.V209M on NM_024889.5) | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs930707048, COSV63056720; called by muse, mutect2, varscan2
- PLG | c.626G>T p.W209L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51986246; called by muse, mutect2, varscan2
- PNPLA1 | c.892C>G p.R298G (on ENST00000394571 / NM_001374623.1; = p.R203G on NM_173676.2) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100462899; called by muse, mutect2, varscan2
- POLQ | c.3107G>A p.S1036N | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.006); catalogued as COSV51760684; called by muse, mutect2
- PPARGC1A | c.1058A>T p.E353V | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53533229; called by muse, mutect2, varscan2
- PPARGC1B | c.2146G>T p.G716W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV58532883; called by muse, mutect2, varscan2
- PPP1R3B | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60100201; called by muse, mutect2, varscan2
- PRAMEF1 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60017757; called by muse, mutect2, varscan2
- PRDM9 | c.1745G>T p.C582F | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57012741; called by muse, mutect2, varscan2
- PRKACB | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65761088; called by muse, mutect2, varscan2
- PRR30 | c.1178C>A p.P393H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV53208104, COSV99574494; called by muse, mutect2, varscan2
- PTGER3 | c.668A>G p.H223R | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs890399816, COSV100139629; called by muse, mutect2
- PTPN4 | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55308621, COSV99751565; called by muse, mutect2, varscan2
- PTPRB | c.3678G>T p.E1226D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as COSV54252562; called by muse, mutect2, varscan2
- PTPRB | c.3067G>T p.A1023S | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV54236729, COSV54252585; called by muse, mutect2, varscan2
- PXDN | c.2232C>A p.H744Q | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV53245656; called by muse, mutect2, varscan2
- PXDNL | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as rs923959337, COSV62497759; called by muse, mutect2, varscan2
- RAB3IP | c.1356G>T p.Q452H (on ENST00000550536 / NM_175623.4; = p.Q436H on NM_022456.5) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV56086517; called by muse, mutect2, varscan2
- RELCH | c.484G>T p.G162* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV56891836; called by muse, mutect2, varscan2
- RELCH | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.263); catalogued as COSV56891853; called by muse, mutect2, varscan2
- RERE | c.1570del p.E524Rfs*49 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as COSV100555878; called by mutect2, pindel, varscan2
- RGS8 | c.159G>T p.W53C (on ENST00000367556 / NM_001369564.2; = p.W71C on NM_033345.3) | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51120223; called by muse, mutect2, varscan2
- RHAG | c.713G>T p.R238M | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV57706276; called by muse, mutect2, varscan2
- RIMBP2 | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55483599; called by muse, mutect2, varscan2
- RNASEL | c.1033del p.A345Qfs*3 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as rs770477877; called by mutect2, pindel, varscan2
- RNF17 | c.152G>A p.C51Y | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55050474; called by muse, mutect2
- RNMT | c.367A>T p.T123S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV51090664; called by muse, mutect2, varscan2
- ROGDI | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs749565672, COSV59020646; called by muse, mutect2
- RP1 | c.4946G>T p.G1649V | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV55125922; called by muse, mutect2, varscan2
- RP1L1 | c.6055G>T p.E2019* | Nonsense Mutation (SNP) | VAF 26/198 reads (13%) | catalogued as COSV66759897, COSV66761368; called by muse, mutect2, varscan2
- RPN2 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV52908767; called by muse, mutect2
- RXFP3 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as COSV57505826, COSV57508112; called by muse, mutect2
- RYR2 | c.2206T>A p.C736S | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.163); catalogued as COSV63711497; called by muse, mutect2, varscan2
- RYR2 | c.7271G>C p.R2424T | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63711504; called by muse, mutect2, varscan2
- RYR2 | c.7876G>T p.G2626W | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63705290, COSV63711507; called by muse, mutect2, varscan2
- SCML4 | c.783G>T p.L261F | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV64637522; called by muse, mutect2
- SCN10A | c.3529G>T p.D1177Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV71861708; called by muse, mutect2, varscan2
- SCN11A | c.2717C>A p.T906N | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV56577813; called by muse, mutect2, varscan2
- SCN3A | c.2504G>A p.S835N | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV51823472; called by muse, mutect2, varscan2
- SCYL2 | c.2765A>T p.N922I | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV62570640; called by muse, mutect2, varscan2
- SEC31B | c.3092A>T p.Q1031L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV64845635; called by muse, mutect2, varscan2
- SECISBP2 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 28/168 reads (17%) | catalogued as rs952834034, CM120693, COSV60530028; called by muse, mutect2, varscan2
- SEMA7A | c.640A>C p.T214P | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56092280; called by muse, mutect2, varscan2
- SEMA7A | c.500G>T p.R167I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV56092287; called by muse, mutect2, varscan2
- SERINC2 | c.457G>T p.G153C (on ENST00000373709 / NM_178865.5; = p.G157C on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371327989; called by muse, mutect2, varscan2
- SERINC5 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV72597162; called by muse, mutect2, varscan2
- SERPINB8 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.104); catalogued as rs758705957, COSV54640588; called by muse, mutect2, varscan2
- SEZ6L2 | c.543A>T p.E181D (on ENST00000308713 / NM_001114099.3; = p.E111D on NM_012410.4) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV58103490; called by muse, mutect2, varscan2
- SH3BP5 | c.380A>T p.E127V | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53746521; called by muse, mutect2, varscan2
- SIGLEC5 | c.580C>A p.R194S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV55783698; called by muse, varscan2
- SLC14A1 | c.109T>C p.Y37H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100425276; called by muse, mutect2, varscan2
- SLC14A1 | c.110A>T p.Y37F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.179); catalogued as COSV100425277; called by muse, mutect2, varscan2
- SLC22A7 | c.428T>A p.L143Q (on ENST00000372585 / NM_153320.2; = p.L141Q on NM_006672.3) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65356161; called by muse, mutect2
- SLC27A3 | c.259C>A p.R87S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as COSV55165642; called by muse, mutect2
- SLC6A15 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.056); catalogued as COSV57029244; called by muse, mutect2, varscan2
- SLIT2 | c.4195G>A p.E1399K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV56593719; called by muse, mutect2, varscan2
- SLITRK2 | c.1741A>T p.S581C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.213); catalogued as COSV59428453; called by muse, mutect2, varscan2
- SLITRK4 | c.2386G>T p.G796C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV62025982; called by muse, mutect2, varscan2
- SLITRK5 | c.299A>T p.E100V | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.322); catalogued as COSV100281173; called by muse, mutect2, varscan2
- SNAI2 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV50079752; called by muse, mutect2, varscan2
- SOBP | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV58002523; called by muse, mutect2, varscan2
- SOX10 | c.1028C>A p.P343H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100704196; called by muse, varscan2
- SOX10 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs754480545, COSV100704198; called by muse, varscan2
- SPDYC | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV65865662; called by muse, mutect2, varscan2
- SPRR2B | c.152A>T p.Q51L | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100482341; called by muse, mutect2, varscan2
- STARD13 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55228707, COSV55236184; called by muse, mutect2, varscan2
- STBD1 | c.1064G>T p.W355L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52954416; called by muse, mutect2, varscan2
- STIM2 | c.1541G>T p.R514L | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52839580, COSV52843323; called by muse, mutect2, varscan2
- STK4 | c.601T>C p.Y201H | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65671964; called by muse, mutect2
- STRC | c.3547A>T p.R1183W | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68660399; called by muse, mutect2, varscan2
- SUPT20H | c.1817-1G>T p.X606_splice (on ENST00000350612 / NM_001014286.3; = p.X607_splice on NM_017569.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 17/118 reads (14%) | catalogued as COSV62248825; called by muse, mutect2, varscan2
- SYNE1 | c.22928T>G p.L7643W (on ENST00000367255 / NM_182961.4; = p.L7572W on NM_033071.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55092657; called by muse, mutect2, varscan2
- SYNE1 | c.4983G>C p.E1661D (on ENST00000367255 / NM_182961.4; = p.E1668D on NM_033071.3) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55092719, COSV99577549; called by muse, mutect2, varscan2
- TAOK3 | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66827637; called by muse, mutect2
- TCEAL3 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs1454972918, COSV54581439; called by muse, mutect2
- TCEAL6 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV65654254; called by muse, mutect2, varscan2
- TDP1 | c.484A>T p.N162Y | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100188117; called by muse, mutect2, varscan2
- TDRD3 | c.302A>G p.H101R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs17855091, COSV52163634; called by muse, mutect2, varscan2
- TDRD9 | c.3919C>A p.L1307I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.371); catalogued as COSV59155372; called by muse, mutect2, varscan2
- TENM3 | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV69318349; called by muse, mutect2, varscan2
- TEX11 | c.1907A>C p.Q636P (on ENST00000344304; = p.Q621P on NM_031276.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV60238499; called by muse, mutect2, varscan2
- TEX15 | c.5509A>G p.N1837D (on ENST00000256246; = p.N2220D on NM_001350162.2) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56353222; called by muse, mutect2, varscan2
- THBS2 | c.1288T>G p.C430G | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV64682051; called by muse, mutect2, varscan2
- TKTL2 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV54921104; called by muse, mutect2, varscan2
- TLR10 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV58302228; called by muse, mutect2, varscan2
- TLR4 | c.769C>T p.R257C (on ENST00000355622 / NM_138554.5; = p.R217C on NM_003266.4) | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs201835255, COSV62924181; called by muse, mutect2, varscan2
- TLR4 | c.1596C>A p.F532L (on ENST00000355622 / NM_138554.5; = p.F492L on NM_003266.4) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs34953464, COSV62924531; called by muse, mutect2, varscan2
- TMC5 | c.1237-1G>T p.X413_splice (on ENST00000396229 / NM_001105248.1; = p.X167_splice on NM_024780.5) | Splice Site (SNP) | VAF 12/124 reads (10%) | catalogued as COSV54909515; called by muse, mutect2
- TMEM18 | c.178+1G>T p.X60_splice | Splice Site (SNP) | VAF 14/82 reads (17%) | catalogued as COSV55245210; called by muse, mutect2, varscan2
- TPX2 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV55922713; called by muse, mutect2
- TREM2 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV100632698; called by mutect2, varscan2
- TRIM72 | c.778C>A p.R260S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.195); catalogued as COSV59068775, COSV59069984; called by muse, mutect2
- TRIML2 | c.217T>G p.S73A | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV58719221; called by muse, mutect2
- TRIP11 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868365156, COSV50957671; called by muse, mutect2, varscan2
- TSHZ3 | c.2414C>A p.S805* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV53681753, COSV53682036; called by muse, mutect2, varscan2
- TTN | c.100631C>A p.T33544N (on ENST00000591111; = p.T26120N on NM_003319.4) | Missense Mutation (SNP) | VAF 31/293 reads (11%) | PolyPhen possibly damaging (0.891); catalogued as COSV60324094; called by muse, mutect2, varscan2
- TTN | c.81839G>T p.G27280V (on ENST00000591111; = p.G19856V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/242 reads (6%) | PolyPhen possibly damaging (0.88); catalogued as COSV60324131; called by muse, mutect2
- TTN | c.78134T>C p.V26045A (on ENST00000591111; = p.V18621A on NM_003319.4) | Missense Mutation (SNP) | VAF 23/212 reads (11%) | PolyPhen benign (0.013); catalogued as COSV60324172; called by muse, mutect2, varscan2
- TTN | c.5918C>G p.T1973S (on ENST00000591111; = p.T1927S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/264 reads (9%) | PolyPhen benign (0); catalogued as COSV60324215; called by muse, mutect2
- TUT1 | c.14A>G p.D5G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs778420150, COSV53471895; called by muse, mutect2
- TUT4 | c.4166A>T p.Q1389L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV57119536; called by muse, mutect2, varscan2
- TXNRD1 | c.482A>G p.Y161C (on ENST00000525566 / NM_001093771.3; = p.Y63C on NM_003330.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs780170129, COSV61601449; called by muse, mutect2, varscan2
- UBE2Q2 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 58/318 reads (18%) | catalogued as COSV51196552; called by muse, mutect2, varscan2
- UBR4 | c.7083A>G p.I2361M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV64398669; called by muse, mutect2, varscan2
- UGT2A3 | c.1363C>A p.L455I | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52361987; called by muse, mutect2, varscan2
- UGT2B28 | c.950C>A p.T317K | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV59434236; called by muse, mutect2, varscan2
- UNC13A | c.2045T>A p.V682E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53209392; called by muse, mutect2, varscan2
- UNC79 | c.5093C>A p.S1698Y (on ENST00000393151 / NM_001346218.2; = p.S1521Y on NM_020818.5) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.444); catalogued as COSV56408853; called by muse, mutect2, varscan2
- USH2A | c.6420G>T p.Q2140H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56430186; called by muse, mutect2, varscan2
- USH2A | c.2917C>G p.Q973E | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV56430220; called by muse, mutect2
- USH2A | c.2499C>A p.N833K | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100241417, COSV56430261; called by muse, mutect2, varscan2
- USP14 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.542); catalogued as COSV55283328; called by muse, mutect2, varscan2
- USP51 | c.1876G>T p.A626S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.047); catalogued as COSV72351937; called by muse, mutect2, varscan2
- UTRN | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62347063; called by muse, mutect2, varscan2
- VMP1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 44/510 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as COSV51864345, COSV99031686; called by muse, mutect2
- WDR24 | c.383G>A p.R128H (on ENST00000248142; = p.R66H on NM_032259.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs780163101, COSV50197409; called by muse, mutect2, varscan2
- WIPI1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV50931605; called by muse, mutect2
- WLS | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99260426; called by muse, mutect2, varscan2
- XPO5 | c.2572A>T p.M858L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54834771; called by muse, mutect2, varscan2
- YIPF5 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV50823605; called by muse, mutect2, varscan2
- ZBTB39 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100268204; called by muse, mutect2, varscan2
- ZEB2 | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as rs775773250, COSV57965632; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.761); catalogued as rs781320407, COSV57640112; called by muse, mutect2, varscan2
- ZNF131 | c.1597G>A p.E533K (on ENST00000509156 / NM_001330707.2; = p.E499K on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV61004397; called by muse, mutect2
- ZNF214 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53483522; called by muse, mutect2, varscan2
- ZNF22 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as rs898967621, COSV53584050; called by muse, mutect2, varscan2
- ZNF267 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV56256114; called by muse, mutect2, varscan2
- ZNF292 | c.6731G>T p.G2244V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.273); catalogued as COSV60546237; called by muse, mutect2, varscan2
- ZNF318 | c.2141A>T p.K714M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58937251; called by muse, mutect2, varscan2
- ZNF470 | c.1571T>A p.L524H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100401398; called by muse, mutect2, varscan2
- ZNF534 | c.490A>C p.S164R (on ENST00000332323 / NM_001143939.3; = p.S151R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs1568444326, COSV56520724; called by muse, mutect2, varscan2
- ZNF536 | c.1350C>A p.S450R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs778404232, COSV62833417; called by muse, mutect2, varscan2
- ZNF536 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV62833421; called by muse, mutect2, varscan2
- ZNF585B | c.2299A>T p.S767C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV57216916; called by muse, mutect2, varscan2
- ZNF770 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62544995; called by muse, mutect2, varscan2
- ZNF813 | c.1640G>C p.G547A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV67177979; called by muse, varscan2
- ZNF836 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100441243; called by muse, mutect2, varscan2
- ZNF99 | c.2022G>C p.E674D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV68056638; called by muse, mutect2, varscan2
- ZSWIM2 | c.749C>G p.T250S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV54574232, COSV54579212; called by muse, mutect2
- ACACA | c.5831A>T p.H1944L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRB3 | c.695dup p.E233Gfs*31 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- AHDC1 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.118); called by muse, mutect2
- ANO7 | c.30del p.L11Sfs*13 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- CNTN4 | c.135dup p.V46Sfs*6 | Frame Shift Ins (INS) | VAF 31/180 reads (17%) | called by mutect2, pindel, varscan2
- COL16A1 | c.1512del p.D505Tfs*59 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- CSN1S1 | c.485del p.P162Hfs*33 | Frame Shift Del (DEL) | VAF 34/271 reads (13%) | called by mutect2, pindel, varscan2
- DNAH8 | c.4864del p.A1622Qfs*38 | Frame Shift Del (DEL) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- FRG2C | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, varscan2
- IGBP1P2 | c.616A>T p.S206C | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- IGKV1-16 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, varscan2
- KIF2B | c.1794dup p.E599* | Frame Shift Ins (INS) | VAF 40/141 reads (28%) | called by mutect2, pindel, varscan2
- KLHL4 | c.1728dup p.G577Wfs*3 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | called by mutect2, pindel
- NBPF15 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR10K2 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- POU3F3 | c.1359del p.W453Cfs*12 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel*
- PSEN2 | c.1142del p.G381Afs*21 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- RIMS2 | c.2860dup p.S954Kfs*25 (on ENST00000666250 / NM_001348490.2; = p.S762Kfs*25 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- TPH1 | c.568del p.C190Afs*32 | Frame Shift Del (DEL) | VAF 39/369 reads (11%) | called by mutect2, pindel, varscan2
- ADCY6 | c.879G>T p.V293= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV57170307; called by muse, mutect2, varscan2
- ADGRL3 | c.3264C>T p.F1088= (on ENST00000506720 / NM_001322402.2; = p.F1020= on NM_015236.6) | Silent (SNP) | VAF 18/167 reads (11%) | catalogued as COSV72231855; called by muse, mutect2, varscan2
- AKAP9 | c.7179G>A p.K2393= (on ENST00000359028; = p.K2369= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs770247481, COSV62357241; called by muse, mutect2, varscan2
- ARHGAP39 | c.864G>A p.L288= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV52775475; called by muse, mutect2
- ARSF | c.813G>T p.A271= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV63839316, COSV63840997; called by muse, mutect2, varscan2
- ATP2B3 | c.2050C>A p.R684= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99685769; called by muse, mutect2, varscan2
- BCAS3 | c.294T>C p.S98= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV66781462; called by muse, mutect2, varscan2
- C16orf78 | c.768G>T p.V256= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV54558294; called by muse, mutect2, varscan2
- CBFA2T2 | c.549C>T p.P183= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100656518; called by muse, mutect2, varscan2
- CCDC63 | c.732G>A p.Q244= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1037064850, COSV57530926; called by muse, mutect2, varscan2
- CCN4 | c.189G>T p.P63= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1236323552, COSV51535426; called by muse, mutect2, varscan2
- CES1 | c.1197C>A p.A399= (on ENST00000361503 / NM_001025194.2; = p.A398= on NM_001266.5) | Silent (SNP) | VAF 20/197 reads (10%) | catalogued as COSV62089960; called by muse, mutect2, varscan2
- CHRM1 | c.939C>T p.A313= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1173836875, COSV61007601; called by muse, mutect2
- CHRNA7 | c.234G>T p.L78= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as COSV60975867; called by muse, mutect2, varscan2
- CLDN7 | c.378C>T p.F126= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100598241; called by muse, mutect2, varscan2
- CYP2F1 | c.18A>T p.T6= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV58528776; called by muse, mutect2, varscan2
- CYP4F22 | c.471C>A p.R157= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV54111614; called by muse, mutect2, varscan2
- DDHD2 | c.1815A>G p.P605= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1217285131, COSV68158740; called by muse, mutect2
- DLG5 | c.1407G>T p.A469= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV64949887; called by muse, mutect2, varscan2
- DLGAP1 | c.2403G>A p.Q801= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV59833208; called by muse, mutect2, varscan2
- DPYSL4 | c.894C>A p.A298= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV58309788; called by muse, mutect2, varscan2
- EGFR | c.2259G>T p.P753= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV51815487, COSV51844009; called by muse, varscan2
- EPB41L3 | c.702G>A p.Q234= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV59466961; called by muse, mutect2
- EPHA3 | c.1179G>T p.T393= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV60709194, COSV60725879; called by muse, mutect2, varscan2
- ETNPPL | c.1332C>A p.T444= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV56597421, COSV56597512; called by muse, mutect2, varscan2
- FBXW7 | c.886C>T p.L296= (on ENST00000281708 / NM_001349798.2; = p.L216= on NM_018315.5) | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV55954945; called by muse, mutect2
- FFAR3 | c.729G>T p.V243= | Silent (SNP) | VAF 12/217 reads (6%) | catalogued as COSV100588303; called by muse, mutect2
- FOXB2 | c.279C>T p.C93= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1409704849, COSV65022491; called by muse, mutect2, varscan2
- FOXG1 | c.822G>T p.R274= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV57399381; called by muse, varscan2
- FRMD6 | c.1485A>T p.G495= (on ENST00000344768 / NM_001267046.2; = p.G487= on NM_152330.4) | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV61090638; called by muse, mutect2, varscan2
- GBP6 | c.1440C>A p.A480= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV65012560, COSV65012612; called by muse, mutect2, varscan2
- GPR149 | c.1695G>A p.G565= | Silent (SNP) | VAF 35/238 reads (15%) | catalogued as COSV67669792; called by muse, mutect2, varscan2
- GPR50 | c.1173A>G p.R391= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV54442577; called by muse, mutect2, varscan2
- GRAMD1B | c.561G>T p.G187= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV59210308; called by muse, mutect2, varscan2
- GRIK4 | c.1470C>T p.I490= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as rs375591719, COSV70806937; called by muse, mutect2, varscan2
- HEY1 | c.120C>T p.S40= | Silent (SNP) | VAF 102/421 reads (24%) | catalogued as rs528107512, COSV61233632; called by muse, mutect2, varscan2
- HINT3 | c.525C>T p.H175= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99996228; called by muse, mutect2, varscan2
- HMBS | c.276G>C p.L92= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV53830056; called by muse, mutect2, varscan2
- IGFLR1 | c.516C>T p.T172= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs778955833, COSV53076464; called by muse, mutect2, varscan2
- IL17RE | c.1005G>A p.L335= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as COSV99925261; called by muse, mutect2, varscan2
- INPP4B | c.1509G>A p.V503= | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as COSV53743869; called by muse, mutect2, varscan2
- INSYN2A | c.627C>G p.L209= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV54758484; called by muse, mutect2, varscan2
- KCNB2 | c.1512C>A p.S504= | Silent (SNP) | VAF 7/144 reads (5%) | catalogued as COSV73052845; called by muse, mutect2
- KDM1B | c.1761A>G p.A587= (on ENST00000449850; = p.A355= on NM_153042.4) | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs747939103, COSV52814437; called by muse, mutect2, varscan2
- KIR2DL4 | c.462G>T p.L154= (on ENST00000396284; = p.L115= on NM_001080770.2) | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as COSV60880107; called by muse, varscan2
- KRT73 | c.1527G>T p.G509= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV59839584, COSV99988845; called by muse, mutect2
- LRIG3 | c.1506G>A p.T502= | Silent (SNP) | VAF 19/178 reads (11%) | catalogued as rs368520634, COSV57863753, COSV57868540; called by muse, mutect2, varscan2
- LRP2 | c.3984G>T p.L1328= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV55572460; called by muse, mutect2, varscan2
- MED12L | c.4902C>T p.V1634= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as rs781362219, COSV56391784; called by muse, mutect2, varscan2
- MFAP1 | c.1227G>A p.E409= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV51040962; called by muse, mutect2, varscan2
- MUC16 | c.22587T>A p.T7529= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV67491164; called by muse, mutect2, varscan2
- MUC16 | c.21915C>G p.T7305= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV67491172; called by muse, mutect2, varscan2
- MUC5B | c.13215T>A p.T4405= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV71595217; called by muse, mutect2, varscan2
- MYMK | c.366C>A p.I122= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs565261423, COSV60601535; called by muse, mutect2, varscan2
- NCOA1 | c.1170C>T p.V390= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV56052477; called by muse, mutect2
- NEK2 | c.31T>C p.L11= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV65357262; called by muse, mutect2, varscan2
- NEK4 | c.307C>T p.L103= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as COSV51783143; called by muse, mutect2
- NES | c.1440G>A p.K480= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as COSV63962808; called by muse, mutect2, varscan2
- NEUROG2 | c.345G>T p.L115= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV57638102; called by muse, mutect2, varscan2
- NHEJ1 | c.735C>A p.S245= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV59432685; called by muse, mutect2
- NRXN1 | c.4236C>G p.A1412= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV60520715; called by muse, mutect2, varscan2
- NUP62 | c.1440G>T p.A480= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV61313553; called by muse, mutect2, varscan2
- OR2L13 | c.423G>T p.V141= | Silent (SNP) | VAF 49/259 reads (19%) | catalogued as COSV63554292, COSV63560396; called by muse, mutect2, varscan2
- OR2M3 | c.798C>A p.R266= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as COSV71759263; called by muse, mutect2, varscan2
- OR4C6 | c.582C>A p.G194= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV58604709, COSV58606110; called by muse, mutect2, varscan2
- OR52K2 | c.33A>T p.P11= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV57835803; called by muse, mutect2, varscan2
- OR56A3 | c.780G>A p.L260= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as rs757771620, COSV61569964; called by muse, mutect2, varscan2
- P2RY12 | c.705C>T p.N235= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs766571463, COSV56395696; called by muse, mutect2, varscan2
- PATZ1 | c.597C>T p.S199= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV53231161; called by muse, mutect2, varscan2
- PCDH15 | c.2502T>A p.A834= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as COSV57387951; called by muse, mutect2, varscan2
- PCDHB6 | c.1260G>A p.T420= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV50704440, COSV50726398; called by muse, mutect2, varscan2
- PCF11 | c.4401T>C p.I1467= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV53537327; called by muse, mutect2, varscan2
- PIKFYVE | c.1536C>T p.A512= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as rs761365321, COSV52248598; called by muse, mutect2
- PNLIPRP3 | c.63C>T p.C21= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as rs1434408114, COSV65049622; called by muse, mutect2, varscan2
- POM121L12 | c.282C>T p.S94= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1038709836, COSV68692409; called by muse, mutect2, varscan2
- PRSS1 | c.342C>A p.S114= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as COSV61193928; called by muse, varscan2
- PSG5 | c.753C>T p.Y251= | Silent (SNP) | VAF 23/204 reads (11%) | catalogued as COSV100742912, COSV61655276; called by muse, mutect2, varscan2
- PTPRB | c.93T>C p.C31= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV51746730; called by muse, mutect2, varscan2
- RBBP4 | c.357C>A p.I119= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV65133393; called by muse, mutect2, varscan2
- RYR2 | c.1584C>G p.S528= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV100771766, COSV63680002, COSV63711489; called by muse, mutect2, varscan2
- SAMD9 | c.4302A>G p.L1434= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as rs763275094, COSV66074981; called by muse, mutect2, varscan2
- SBF1 | c.1674C>T p.N558= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1285143336, COSV62370288, COSV62370873; called by muse, mutect2, varscan2
- SEPTIN8 | c.864C>T p.L288= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV51525083; called by muse, mutect2, varscan2
- SGO2 | c.1344C>T p.P448= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as rs781114196, COSV63417886; called by muse, mutect2
- SLC12A6 | c.1575G>A p.L525= (on ENST00000354181 / NM_001365088.1; = p.L474= on NM_005135.2) | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2
- SLC22A16 | c.1591C>A p.R531= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV57934253; called by muse, mutect2, varscan2
- SLC26A7 | c.759G>A p.R253= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV52586418, COSV52593571; called by muse, mutect2, varscan2
- SLC4A10 | c.1281C>T p.L427= (on ENST00000446997 / NM_001354461.2; = p.L397= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV55798175; called by muse, mutect2, varscan2
- SLC6A2 | c.1155C>A p.G385= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV54922964; called by muse, mutect2, varscan2
- SLITRK5 | c.300G>A p.E100= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as COSV100281176; called by muse, mutect2, varscan2
- SON | c.1695G>T p.S565= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV51669954; called by muse, mutect2, varscan2
- SORBS1 | c.1380C>T p.Y460= (on ENST00000361941 / NM_001034954.2; = p.Y250= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV53364847; called by muse, mutect2, varscan2
- SPEM1 | c.729G>T p.L243= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV57211925; called by muse, mutect2, varscan2
- SPNS3 | c.516C>T p.R172= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs146044768; called by muse, mutect2, varscan2
- SUPT6H | c.21C>T p.S7= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs375207346; called by muse, mutect2
- SV2B | c.1908T>C p.F636= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV57701929; called by muse, mutect2, varscan2
- TACC2 | c.2280T>C p.D760= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV57771743; called by muse, mutect2, varscan2
- TAS1R1 | c.1275C>A p.I425= | Silent (SNP) | VAF 20/246 reads (8%) | catalogued as COSV59840735; called by muse, mutect2
- TAS1R2 | c.1611C>A p.A537= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV64747072; called by muse, mutect2
- TDP1 | c.483G>T p.G161= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100188114; called by muse, mutect2, varscan2
- TMED6 | c.600C>T p.Y200= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs755801867, COSV54742510; called by muse, mutect2, varscan2
- TMEM155 | c.48C>A p.S16= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100530083; called by muse, mutect2, varscan2
- TMEM59L | c.865C>T p.L289= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV53243485; called by muse, mutect2
- TMPRSS13 | c.501G>T p.P167= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV70627561, COSV70627724; called by muse, mutect2, varscan2
- TMPRSS9 | c.1179C>T p.A393= (on ENST00000648592; = p.A359= on NM_182973.2) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV60231129; called by muse, mutect2, varscan2
- TNPO1 | c.2664A>G p.L888= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as COSV61523840; called by muse, mutect2, varscan2
- TPD52L3 | c.174G>T p.G58= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100096145; called by muse, mutect2, varscan2
- TRBC2 | c.402C>A p.T134= | Silent (SNP) | VAF 48/604 reads (8%) | catalogued as rs782137634; called by muse, mutect2
- TYRO3 | c.2082G>T p.L694= | Silent (SNP) | VAF 27/212 reads (13%) | catalogued as COSV55486682; called by muse, mutect2, varscan2
- TYW3 | c.336G>A p.L112= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV63803329; called by muse, mutect2, varscan2
- UBQLN1 | c.861A>T p.A287= | Silent (SNP) | VAF 26/245 reads (11%) | catalogued as COSV57409316; called by muse, mutect2, varscan2
- UGT2A3 | c.234T>C p.H78= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1363545083, COSV52361997; called by muse, mutect2, varscan2
- USF2 | c.834G>T p.G278= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99723181; called by muse, mutect2, varscan2
- USH2A | c.15504C>A p.G5168= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV56430160; called by muse, mutect2, varscan2
- VWC2L | c.34C>T p.L12= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV56975665; called by muse, mutect2, varscan2
- XDH | c.2688G>A p.R896= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs756823487, COSV65151071; called by muse, mutect2, varscan2
- ZNF432 | c.729C>A p.S243= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV55418337; called by muse, mutect2, varscan2
- ZNF676 | c.1188C>A p.P396= (on ENST00000650058; = p.P364= on NM_001001411.3) | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs1454661475, COSV68092734; called by muse, varscan2
- AC073310.1 | n.727C>A | RNA (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- CD200R1 | c.68-16749G>A | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as rs145811094; called by muse, mutect2, varscan2
- FBXL7 | c.740-1212C>T | Intron (SNP) | VAF 9/74 reads (12%) | catalogued as rs577167019, COSV61643974; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85731C>T | Intron (SNP) | VAF 24/181 reads (13%) | catalogued as COSV72275114, COSV72282976; called by muse, mutect2, varscan2
- NACA | c.71-2372A>T | Intron (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100771613; called by muse, mutect2, varscan2
- OFCC1 | n.556+3383T>A | Intron (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- SNORD113-9 | n.38G>T | RNA (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- SNORD113-9 | n.39G>T | RNA (SNP) | VAF 19/136 reads (14%) | catalogued as rs1316077963; called by muse, mutect2, varscan2
- SYNE1 | c.24977-1747A>G | Intron (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99577466; called by muse, mutect2
- TMEM132E | chr17:34578941 C>G | 5'Flank (SNP) | VAF 23/176 reads (13%) | catalogued as rs754961448; called by muse, mutect2, varscan2
- UVSSA | c.*9609G>T | 3'UTR (SNP) | VAF 29/226 reads (13%) | catalogued as COSV61351593; called by muse, varscan2
- XIRP2 | c.*207A>T | 3'UTR (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99747021; called by muse, mutect2, varscan2
